Surgical pathology report (de-identified scan), TCGA case TCGA-32-2491, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-2491-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right temporal brain tumor - frozen
2. Right temporal brain tumor - perm

TCGA-32-2491

CLINICAL DIAGNOSIS:

Brain tumor

GROSS DESCRIPTION:

1. Received fresh for frozen section are three tan pink soft tissue fragments aggregating to 0.5 x 0.3 x 0.1 cm. Entirely frozen on one chuck.

FROZEN SECTION AND SMEAR PREP DIAGNOSIS:

GLIOBLASTOMA MULTIFORME.

2. Received in formalin are multiple tan pink soft tissue fragments aggregating to 1.5 x 0.7 x 0.1 cm. Entirely submitted in one cassette.

MICROSCOPIC DESCRIPTION:

- 1, 2. Sections demonstrate a markedly hypercellular glial neoplasm, the cells of which resemble moderately to markedly atypical astrocytes. Scattered mitotic figures are seen. Microvascular proliferation is present. Specimen 2 demonstrates large areas of confluent tumor necrosis.

DIAGNOSIS:

- 1, 2. TEMPORAL BRAIN TUMOR (FROZEN SECTION AND PERMANENT):
GLIOBLASTOMA MULTIFORME

Source: NCI Genomic Data Commons file 25e86e2a-a8ed-4d26-a2d4-d86b52b9de3a (TCGA-32-2491.ACA82E7C-2BAF-49FB-BB70-B05D479CE2A4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).